Somatic mutation profile of tumor specimen TCGA-BB-4223-01A (aliquot TCGA-BB-4223-01A-01D-1434-08) from TCGA case TCGA-BB-4223, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 48.2 years (17,608 days).
Specimen TCGA-BB-4223-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23f4d596-2592-4c60-8528-e928c775d971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-4223-10A (Blood Derived Normal), aliquot TCGA-BB-4223-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c01f779-0685-4a6f-80b1-cdb4a28a050c

The open-access MAF lists 162 somatic variants for this specimen: 115 protein-altering or splice-affecting, 42 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 42, Nonsense Mutation 10, Intron 2, Frame Shift Ins 2, Splice Site 1, 5'Flank 1, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 34/119 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACB | c.3097C>T p.R1033W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776904109, COSV58146327; called by muse, mutect2, varscan2
- ACADM | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100273477; called by muse, mutect2
- ADAMTS9 | c.5459C>T p.T1820M | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as rs746487812, COSV55775369; called by muse, mutect2, varscan2
- AFAP1 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1170420391, COSV100631532; called by muse, mutect2
- AKAP9 | c.1238A>G p.Q413R | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV100662413; called by muse, mutect2, varscan2
- ANKRD17 | c.7057G>A p.G2353R | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.159); catalogued as rs139173196; called by muse, mutect2
- ARSH | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV101139859; called by muse, mutect2
- ASH1L | c.2981G>C p.R994T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100853421; called by muse, varscan2
- ASPM | c.5400A>T p.Q1800H | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV99659780, COSV99660380; called by muse, mutect2, varscan2
- ASTN1 | c.1207C>G p.H403D | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV99921740; called by muse, mutect2
- ATAD2B | c.2382C>G p.F794L | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.292); catalogued as COSV99477682; called by muse, mutect2
- ATP1A4 | c.2725G>A p.G909R | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs764662453, COSV63626691; called by muse, mutect2, varscan2
- BCO2 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs766432726, COSV100730346; called by muse, mutect2, varscan2
- BLOC1S6 | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV99593399; called by muse, mutect2
- BRAF | c.2371C>G p.P791A (on ENST00000288602 / NM_001374244.1; = p.P751A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/720 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99961532; called by muse, mutect2
- BRD4 | c.1182C>G p.I394M | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99650699; called by muse, mutect2
- C3orf70 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.028); catalogued as rs753948081, COSV100621248; called by muse, mutect2
- CALM1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as COSV100811153; called by muse, mutect2, varscan2
- CCDC85A | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.079); catalogued as rs746586844, COSV68149875; called by muse, varscan2
- CDC5L | c.631A>T p.N211Y | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101015047; called by muse, mutect2, varscan2
- CELSR1 | c.5278G>T p.E1760* | Nonsense Mutation (SNP) | VAF 7/168 reads (4%) | catalogued as COSV53090611; called by muse, mutect2
- CETN1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 28/153 reads (18%) | catalogued as COSV100511326; called by muse, mutect2, varscan2
- CILP2 | c.3331C>T p.R1111* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs1348996661, COSV52276221; called by muse, mutect2, varscan2
- CLSPN | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99230920; called by muse, mutect2
- CLSPN | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99230921; called by muse, mutect2
- CPA3 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV56044739, COSV99936167; called by muse, mutect2
- CPXCR1 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.783); catalogued as rs777773578, COSV52164516, COSV99342216; called by muse, mutect2, varscan2
- CREB3L1 | c.201G>C p.K67N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1192182037, COSV99915040; called by muse, mutect2, varscan2
- DCAF16 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV101200436; called by muse, mutect2
- DNAH17 | c.9025G>C p.E3009Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101102359, COSV67758741; called by muse, mutect2
- DST | c.19510C>T p.Q6504* (on ENST00000361203 / NM_001374722.1; = p.Q4201* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99756123, COSV99759360; called by muse, mutect2, varscan2
- DYNC1H1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs797045178, COSV64138607; called by muse, mutect2, varscan2
- DYRK4 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763765045, COSV50538264; called by muse, varscan2
- EDEM1 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56582931; called by muse, mutect2, varscan2
- EPHB3 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100383082; called by muse, mutect2
- EPM2AIP1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 14/349 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs1376195820, COSV99212464; called by muse, mutect2
- FAM155A | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs757208205, COSV65565998, COSV65579689; called by muse, varscan2
- FBN3 | c.7804G>C p.D2602H | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99560959; called by muse, mutect2, varscan2
- FXR1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV59766780, COSV99976383; called by muse, mutect2, varscan2
- H2AC21 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 15/319 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV100479928; called by muse, mutect2
- HFM1 | c.1460G>C p.R487T | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99646006; called by muse, mutect2
- HOXA4 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100415473; called by muse, mutect2
- IFI16 | c.1288C>G p.Q430E | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV99857593; called by muse, mutect2
- IL23R | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 9/266 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.929); catalogued as COSV100724737; called by muse, mutect2
- ILVBL | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as COSV54621689, COSV99654870; called by muse, mutect2
- ISLR2 | c.31T>G p.W11G | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV100679565; called by muse, mutect2, varscan2
- KCNMB3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs893197704, COSV62895843; called by muse, mutect2, varscan2
- KDM7A | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs1395322600, COSV99134492; called by muse, mutect2
- KLK9 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99143981; called by muse, mutect2, varscan2
- KMT2E | c.2318C>G p.S773C | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99996339; called by muse, mutect2
- LAPTM4A | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV99442393; called by muse, mutect2
- LRRC7 | c.4111-1G>C p.X1371_splice (on ENST00000651989 / NM_001370785.2; = p.X1291_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 8/230 reads (3%) | catalogued as COSV99226369, COSV99227009; called by muse, mutect2
- LYST | c.1130G>C p.R377T | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.347); catalogued as COSV101089418; called by muse, mutect2
- MAP3K8 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99552135; called by muse, mutect2
- MTMR4 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 34/706 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.013); catalogued as COSV100050675; called by muse, mutect2
- MUC6 | c.5663C>T p.S1888F | Missense Mutation (SNP) | VAF 137/1306 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101424595; called by muse, varscan2
- MVP | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.146); catalogued as COSV100651589; called by muse, mutect2
- NPR2 | c.2687T>C p.I896T | Missense Mutation (SNP) | VAF 44/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs766790400, COSV100438907; called by muse, mutect2, varscan2
- OBSCN | c.10627G>T p.D3543Y | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV52757250; called by muse, mutect2
- ODC1 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99301286; called by muse, mutect2, varscan2
- OR4C12 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 79/210 reads (38%) | catalogued as rs1356609758, COSV100078503, COSV58860868; called by muse, mutect2, varscan2
- OR5H6 | c.332C>G p.S111C (on ENST00000642105; = p.S95C on NM_001005479.2) | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as COSV101051776; called by muse, mutect2, varscan2
- PAK1IP1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV52584469, COSV99468416, COSV99468494; called by muse, varscan2
- PCBP4 | c.659C>G p.S220* (on ENST00000322099 / NM_033010.2; = p.S177* on NM_020418.4) | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100436997, COSV100437031; called by muse, mutect2, varscan2
- PCDHB16 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV53364654, COSV53365224; called by muse, mutect2
- PLCD4 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV101346896; called by muse, mutect2, varscan2
- PLEKHG2 | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99217486, COSV99218031; called by muse, mutect2
- PLOD2 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV99282787; called by muse, mutect2, varscan2
- PNLDC1 | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 22/559 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51707567; called by muse, mutect2
- PPP2R5D | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV55146501, COSV99775714; called by muse, mutect2
- PRKCZ | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1284558321, COSV101057759; called by muse, mutect2, varscan2
- PRKD3 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as COSV99306153, COSV99306464; called by muse, mutect2, varscan2
- PRR11 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99231543; called by muse, mutect2
- PTPRK | c.4288G>A p.D1430N (on ENST00000368215 / NM_001291984.2; = p.D1431N on NM_002844.4) | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100950603; called by muse, mutect2
- QRICH2 | c.3144G>A p.M1048I | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV99429258; called by muse, mutect2
- RFWD3 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 15/480 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1355086543; called by muse, mutect2
- RRP8 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 7/154 reads (5%) | catalogued as COSV99601913; called by muse, mutect2
- S100G | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV100826849; called by muse, mutect2
- SACS | c.11591C>G p.S3864C | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV101207452; called by muse, mutect2
- SEMA4A | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100740595; called by muse, mutect2
- SGO2 | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV100764680; called by muse, mutect2
- SIGLEC8 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 77/369 reads (21%) | catalogued as rs370177010; called by muse, mutect2, varscan2
- SIM1 | c.200C>G p.S67* | Nonsense Mutation (SNP) | VAF 54/167 reads (32%) | catalogued as COSV99492370; called by muse, mutect2, varscan2
- SLCO2B1 | c.1867G>T p.D623Y | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99214666; called by muse, mutect2, varscan2
- SNX25 | c.1863G>C p.L621F | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99252877; called by muse, mutect2
- SPATA31E1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV100350483; called by muse, mutect2
- ST18 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 170/362 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV52509099; called by muse, mutect2, varscan2
- STRIP2 | c.2172G>C p.W724C | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99973813; called by muse, mutect2
- SVEP1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as rs1042692688, COSV57031238; called by muse, mutect2, varscan2
- SYCP2L | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 144/394 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99305214; called by muse, mutect2, varscan2
- SYT16 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs773454309, COSV70856997; called by muse, mutect2, varscan2
- TAB1 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99336063; called by muse, mutect2, varscan2
- TACC2 | c.8370G>C p.E2790D (on ENST00000334433; = p.E868D on NM_006997.4) | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99587101; called by muse, mutect2
- TASOR | c.3257C>G p.S1086C (on ENST00000355628 / NM_001365636.2; = p.S710C on NM_015224.3) | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV100843561; called by muse, mutect2
- TBCCD1 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV100111985; called by muse, mutect2
- TECR | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99295090; called by muse, mutect2
- TGFBI | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100526501; called by muse, mutect2, varscan2
- TIMELESS | c.3364G>C p.D1122H | Missense Mutation (SNP) | VAF 28/1006 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.361); catalogued as COSV57510471, COSV99973983; called by muse, mutect2
- TOPBP1 | c.2698G>C p.E900Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV53432640, COSV99605336; called by muse, mutect2
- TRIM56 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV100047345; called by muse, mutect2, varscan2
- TRIP10 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 10/273 reads (4%) | catalogued as COSV100505127; called by muse, mutect2
- TTC6 | c.976C>G p.L326V (on ENST00000267368; = p.L1692V on NM_001310135.3) | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99941875; called by muse, mutect2
- UBOX5 | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV99417938; called by muse, mutect2, varscan2
- UBXN4 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV55634447; called by muse, mutect2
- VCAM1 | c.1183G>C p.G395R | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV54119500; called by muse, mutect2
- VPS39 | c.1780G>C p.E594Q (on ENST00000348544 / NM_001301138.2; = p.E583Q on NM_015289.5) | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100529213; called by muse, mutect2
- XPO4 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1316924725, COSV55012760; called by muse, mutect2
- ZNF480 | c.1261C>G p.H421D | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100574181, COSV57995294; called by muse, mutect2
- ZNF704 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 25/906 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); catalogued as COSV100589543, COSV59926877; called by muse, mutect2
- ZSWIM4 | c.2835C>G p.F945L | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99584918; called by muse, mutect2
- CNKSR3 | c.1_2insC p.M1? | Frame Shift Ins (INS) | VAF 131/338 reads (39%) | called by mutect2, pindel*, varscan2
- HRC | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- IQCE | c.822G>A p.K274= | Splice Region (SNP) | VAF 12/354 reads (3%) | called by muse, mutect2
- MRM3 | c.559+1dup | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- ATP1B2 | c.534C>G p.V178= | Silent (SNP) | VAF 144/409 reads (35%) | catalogued as COSV100006895; called by muse, mutect2, varscan2
- CBX1 | c.405G>C p.L135= | Silent (SNP) | VAF 14/354 reads (4%) | catalogued as COSV99848148; called by muse, mutect2
- CCDC34 | c.330G>A p.L110= | Silent (SNP) | VAF 9/242 reads (4%) | catalogued as COSV100156581; called by muse, mutect2
- CCKBR | c.756C>T p.D252= | Silent (SNP) | VAF 67/159 reads (42%) | catalogued as rs747685589, COSV58100637; called by muse, mutect2, varscan2
- CCSAP | c.378G>T p.V126= | Silent (SNP) | VAF 53/175 reads (30%) | catalogued as COSV99497388; called by muse, mutect2, varscan2
- CENPN | c.111G>A p.Q37= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV99548214; called by muse, mutect2, varscan2
- CNDP2 | c.759G>A p.K253= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV100159114; called by muse, varscan2
- CSGALNACT1 | c.717C>T p.L239= | Silent (SNP) | VAF 21/584 reads (4%) | catalogued as rs1563507779, COSV100175001, COSV59982506; called by muse, mutect2
- DLEC1 | c.618G>A p.L206= | Silent (SNP) | VAF 22/564 reads (4%) | catalogued as COSV100342403; called by muse, mutect2
- DLGAP1 | c.564C>T p.R188= | Silent (SNP) | VAF 124/573 reads (22%) | catalogued as rs1403736567, COSV100227437; called by muse, mutect2, varscan2
- DNAAF1 | c.2106C>G p.V702= | Silent (SNP) | VAF 130/316 reads (41%) | catalogued as COSV100499595, COSV58985807, COSV58987685; called by muse, mutect2, varscan2
- DNAH8 | c.12231C>T p.F4077= | Silent (SNP) | VAF 12/324 reads (4%) | catalogued as COSV100545424, COSV59438837; called by muse, mutect2
- DST | c.918G>C p.L306= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100421447; called by muse, mutect2
- FAM13B | c.276C>T p.P92= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- FAN1 | c.2475C>T p.S825= | Silent (SNP) | VAF 24/332 reads (7%) | catalogued as rs1350913647, COSV100755980; called by muse, mutect2
- IFNE | c.330C>T p.L110= | Silent (SNP) | VAF 14/302 reads (5%) | catalogued as rs1396476837, COSV100438863; called by muse, mutect2
- ITGB1 | c.1656C>T p.F552= | Silent (SNP) | VAF 15/287 reads (5%) | catalogued as COSV56488940; called by muse, mutect2
- KHDC1 | c.243C>T p.L81= (on ENST00000370384 / NM_001251874.2; = p.L8= on NM_030568.5) | Silent (SNP) | VAF 15/306 reads (5%) | catalogued as rs1164236437, COSV57615659; called by muse, mutect2
- KIAA2026 | c.5601C>T p.F1867= | Silent (SNP) | VAF 13/418 reads (3%) | catalogued as COSV101199054; called by muse, mutect2
- MRPS9 | c.231G>A p.Q77= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV99306081; called by muse, mutect2
- NEK2 | c.897C>T p.S299= | Silent (SNP) | VAF 16/451 reads (4%) | catalogued as COSV100878634; called by muse, mutect2
- OR2T4 | c.651G>A p.L217= | Silent (SNP) | VAF 14/322 reads (4%) | catalogued as COSV63543612; called by muse, mutect2
- OR52D1 | c.720T>C p.A240= | Silent (SNP) | VAF 12/324 reads (4%) | catalogued as COSV100495229; called by muse, mutect2
- PCED1A | c.9C>T p.F3= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs143418384; called by muse, mutect2, varscan2
- PIGG | c.1269G>A p.L423= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99573897; called by muse, mutect2
- PLIN1 | c.939G>A p.E313= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100261565; called by muse, mutect2
- POLD4 | c.264G>A p.L88= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as COSV100412424; called by muse, mutect2
- POTEF | c.2679C>T p.L893= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV100664936; called by muse, mutect2
- PPM1H | c.399G>A p.L133= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV99955875; called by muse, mutect2, varscan2
- PROC | c.1176G>A p.G392= | Silent (SNP) | VAF 10/256 reads (4%) | catalogued as COSV52166898, COSV99300776; called by muse, mutect2
- PWP1 | c.213C>T p.R71= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as rs1387955652, COSV101338819; called by muse, mutect2, varscan2
- SART3 | c.642C>G p.L214= | Silent (SNP) | VAF 153/276 reads (55%) | catalogued as COSV99934077; called by muse, mutect2, varscan2
- SRCAP | c.2604C>G p.L868= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as COSV99350168; called by muse, mutect2
- TMEM196 | c.372C>A p.L124= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV101337498; called by muse, mutect2
- TPO | c.1812G>A p.E604= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV100221085; called by muse, mutect2, varscan2
- TTN | c.29049G>C p.L9683= (on ENST00000591111; = p.L8756= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/384 reads (4%) | catalogued as COSV60338377; called by muse, mutect2
- TUBGCP2 | c.2253C>T p.L751= | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as rs1369486888, COSV99427754; called by muse, mutect2
- USP1 | c.435G>A p.L145= | Silent (SNP) | VAF 9/241 reads (4%) | catalogued as COSV100375203; called by muse, mutect2
- USP19 | c.387C>G p.V129= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as COSV100026176; called by muse, mutect2
- ZAN | c.5028C>G p.L1676= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100769736; called by muse, mutect2, varscan2
- ZFP1 | c.681C>T p.L227= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100182037; called by muse, mutect2, varscan2
- ZNRD2 | c.279C>G p.L93= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as COSV100326122; called by muse, mutect2
- EEF1B2 | c.331-118G>C | Intron (SNP) | VAF 9/223 reads (4%) | catalogued as COSV99260963; called by muse, mutect2
- EPHB6 | c.*1G>C | 3'UTR (SNP) | VAF 32/81 reads (40%) | catalogued as COSV100844305; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11329G>C | Intron (SNP) | VAF 12/174 reads (7%) | catalogued as COSV99410635; called by muse, mutect2
- MAPKAPK2 | chr1:206682934 C>G | 5'Flank (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- RPL23AP82 | n.795C>T | RNA (SNP) | VAF 42/193 reads (22%) | called by muse, mutect2, varscan2
